FM case AD13037 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Gallbladder.
https://portal.gdc.cancer.gov/cases/da6cde4e-bb66-4679-a25f-c42d8141cddf

Female, 69.3 years: Adenocarcinoma, NOS (ICD-O-3 8140/3) of the gallbladder; primary biopsied or resected from the gallbladder. Tumor nuclei on the sequenced sample's slide: 50% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
